Somatic mutation profile of tumor specimen C3L-07090-01 (aliquot CPT0411260006) from CPTAC case C3L-07090, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 82.9 years (30,297 days).
Specimen C3L-07090-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0f2e65a-a6fc-4359-842c-9a277dc07ebf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07090-31 (Blood Derived Normal), aliquot CPT0411440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed30459f-7219-4114-83ca-d8aa651b825a

The open-access MAF lists 2,424 somatic variants for this specimen: 1,767 protein-altering or splice-affecting, 555 silent, 102 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,235, Silent 555, Frame Shift Del 343, Frame Shift Ins 97, Intron 63, Nonsense Mutation 55, Splice Region 14, 5'UTR 13, 3'UTR 10, 3'Flank 10, Splice Site 9, In Frame Del 8.

Variants (750 of 2,424; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.879del p.A294Lfs*14 | Frame Shift Del (DEL) | VAF 14/162 reads (9%) | catalogued as rs1326932143, CD1313627, COSV99711173; ClinVar: pathogenic; called by mutect2, pindel
- ATP1A3 | c.1043C>T p.T348M (on ENST00000545399 / NM_001256214.2; = p.T335M on NM_152296.5) | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691940; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CFAP20 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 20/215 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs753911484, COSV52630441; called by muse, mutect2, varscan2
- COL5A1 | c.1502del p.P501Lfs*57 | Frame Shift Del (DEL) | VAF 24/271 reads (9%) | catalogued as rs1085307855; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FGFR1 | c.1019C>T p.T340M (on ENST00000447712 / NM_023110.3; = p.T338M on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/397 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1064793123, CM0911318, COSV58331507; ClinVar: likely pathogenic; called by muse, mutect2
- FOXG1 | c.460del p.E154Rfs*38 | Frame Shift Del (DEL) | VAF 22/148 reads (15%) | catalogued as rs398124204; ClinVar: pathogenic; called by mutect2, varscan2
- HSF4 | c.965del p.P322Rfs*74 (on ENST00000521374 / NM_001040667.3; = p.P292Rfs*74 on NM_001538.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 37/292 reads (13%) | catalogued as rs776129797; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KCNMA1 | c.2026del p.Y676Tfs*15 | Frame Shift Del (DEL) | VAF 27/201 reads (13%) | catalogued as rs762705295; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 23/223 reads (10%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 20/166 reads (12%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 50/366 reads (14%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 15/132 reads (11%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 20/117 reads (17%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SF3B4 | c.1060dup p.R354Pfs*132 | Frame Shift Ins (INS) | VAF 27/247 reads (11%) | catalogued as rs782357237; ClinVar: pathogenic; called by mutect2, varscan2
- SLC12A5 | c.1196C>T p.S399L (on ENST00000454036 / NM_001134771.2; = p.S376L on NM_020708.5) | Missense Mutation (SNP) | VAF 30/399 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs1568862550, COSV54787923; ClinVar: pathogenic; called by muse, mutect2
- A1BG | c.1123G>A p.V375I | Missense Mutation (SNP) | VAF 54/380 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.136); catalogued as rs902106978, COSV54052991; called by muse, mutect2, varscan2
- AATK | c.3320C>T p.P1107L (on ENST00000326724 / NM_001080395.3; = p.P1004L on NM_004920.2) | Missense Mutation (SNP) | VAF 45/346 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1204186816; called by mutect2, varscan2
- ABCA10 | c.1245dup p.D416* | Frame Shift Ins (INS) | VAF 17/147 reads (12%) | catalogued as rs1428592950; called by mutect2, pindel, varscan2
- ABCA5 | c.77G>A p.C26Y | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as rs1215729980; called by muse, mutect2, varscan2
- ABCC4 | c.2326G>A p.V776I | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs146708960; called by muse, mutect2, varscan2
- ABCF1 | c.1258C>T p.R420W (on ENST00000326195 / NM_001025091.2; = p.R382W on NM_001090.3) | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs868768673; called by muse, varscan2
- ABHD1 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 34/316 reads (11%) | catalogued as rs759428689; called by muse, mutect2, varscan2
- ABHD5 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1358271126, COSV50006309; called by muse, mutect2, varscan2
- AC010255.2 | c.96dup p.W33Mfs*3 | Frame Shift Ins (INS) | VAF 18/166 reads (11%) | catalogued as rs1173186577; called by mutect2, pindel, varscan2
- AC011455.2 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as rs538595585; called by muse, mutect2, varscan2
- AC015802.6 | c.330del p.K111Sfs*32 | Frame Shift Del (DEL) | VAF 14/110 reads (13%) | catalogued as rs1361582030; called by mutect2, pindel, varscan2
- AC068580.4 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 60/453 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as COSV52587161; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 21/129 reads (16%) | catalogued as rs757016425; called by mutect2, varscan2
- ACHE | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 34/452 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs1466479876; called by muse, mutect2
- ACTL7B | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 13/388 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.081); catalogued as COSV65927579; called by muse, mutect2
- ACTN2 | c.1799G>A p.S600N | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs794728968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACVR1C | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1010563861; called by muse, mutect2, varscan2
- ADAMTS12 | c.2833C>T p.P945S | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61272765; called by muse, mutect2, varscan2
- ADAMTS7 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 32/323 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.117); catalogued as rs534827822; called by muse, mutect2
- ADAMTS8 | c.2152G>A p.V718M | Missense Mutation (SNP) | VAF 43/323 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs747292238; called by muse, mutect2, varscan2
- ADCY2 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs188113151; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 20/146 reads (14%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA2 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764578995; called by muse, mutect2
- ADGRB3 | c.389T>C p.I130T | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV65405642; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 29/208 reads (14%) | catalogued as rs761350619; called by mutect2, varscan2
- ADPGK | c.674A>G p.H225R | Missense Mutation (SNP) | VAF 25/264 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV61173329; called by muse, mutect2
- ADRA2C | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1170395344; called by muse, varscan2
- ADRA2C | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV57467614; called by muse, varscan2
- AGBL3 | c.1914dup p.H639Tfs*25 | Frame Shift Ins (INS) | VAF 13/107 reads (12%) | catalogued as rs750806939; called by mutect2, pindel, varscan2
- AGMAT | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 46/387 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768762536, COSV65435721; called by muse, varscan2
- AHSG | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs746165143; called by muse, mutect2, varscan2
- AIM2 | c.959del p.N320Mfs*7 | Frame Shift Del (DEL) | VAF 26/227 reads (11%) | catalogued as rs752653022, COSV63698332; called by mutect2, pindel, varscan2
- AJM1 | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 46/395 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as rs1300326965; called by muse, mutect2, varscan2
- AKAP3 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs774854628; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 26/132 reads (20%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- ALAD | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 42/324 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs1249890466, COSV52959492; called by muse, varscan2
- ALDH3A1 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs746369217; called by muse, mutect2, varscan2
- ALDH8A1 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1444082586; called by muse, mutect2, varscan2
- ALDH9A1 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370269292; called by muse, mutect2, varscan2
- ALKBH5 | c.93_98del p.A36_A37del | In Frame Del (DEL) | VAF 32/274 reads (12%) | catalogued as rs1355794523; called by mutect2, pindel, varscan2
- ALOX12 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 43/321 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs200546604; called by muse, mutect2, varscan2
- ALPI | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 56/432 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs148557980; called by muse, mutect2, varscan2
- AMER3 | c.2075C>T p.P692L | Missense Mutation (SNP) | VAF 54/416 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs141716978, COSV58465062; called by muse, mutect2, varscan2
- AMOTL2 | c.818del p.P273Lfs*13 | Frame Shift Del (DEL) | VAF 37/296 reads (13%) | catalogued as rs1319526303; called by pindel, varscan2
- ANGPTL7 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs775409689, COSV100816141; called by muse, mutect2, varscan2
- ANKAR | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs779093435; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4594del p.R1532Gfs*5 | Frame Shift Del (DEL) | VAF 40/297 reads (13%) | catalogued as COSV51845823; called by mutect2, pindel, varscan2
- ANKRD29 | c.132C>T p.S44= | Splice Region (SNP) | VAF 48/376 reads (13%) | catalogued as rs374359345; called by muse, mutect2, varscan2
- AP3B2 | c.1592C>T p.T531I | Missense Mutation (SNP) | VAF 40/341 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as rs779983418; called by muse, mutect2, varscan2
- APBB2 | c.219_222del p.N74Sfs*26 | Frame Shift Del (DEL) | VAF 36/312 reads (12%) | catalogued as rs774272543; called by pindel, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 26/168 reads (15%) | catalogued as rs546686089; called by mutect2, varscan2
- APLP2 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99599786; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 20/136 reads (15%) | catalogued as rs772728725, COSV54066450; called by mutect2, varscan2
- ARHGAP11B | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 30/438 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as rs748018819; called by muse, mutect2
- ARHGAP21 | c.2675A>G p.D892G | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as COSV57606237; called by muse, mutect2, varscan2
- ARHGEF1 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as rs782343511, COSV61527129; called by muse, mutect2, varscan2
- ARHGEF15 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 42/353 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1362528188, COSV62726799; called by muse, mutect2, varscan2
- ARHGEF16 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as rs562450072, COSV65681601; called by muse, mutect2
- ARHGEF17 | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 49/367 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1290501676, COSV55238070; called by muse, mutect2, varscan2
- ARHGEF17 | c.2270G>A p.S757N | Missense Mutation (SNP) | VAF 35/316 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs374025043; called by muse, mutect2, varscan2
- ARHGEF3 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.027); catalogued as rs1013498250, COSV58176251; called by muse, mutect2
- ARHGEF33 | c.2255C>T p.A752V | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1022389621; called by muse, mutect2, varscan2
- ARID1B | c.4517G>A p.R1506H | Missense Mutation (SNP) | VAF 52/317 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1449208173, COSV51668801; called by muse, mutect2, varscan2
- ARID5A | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs757817720; called by muse, mutect2, varscan2
- ARID5B | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs1365260841; called by muse, mutect2, varscan2
- ARMH2 | c.136del p.I46Sfs*20 | Frame Shift Del (DEL) | VAF 42/293 reads (14%) | catalogued as rs965020534; called by mutect2, varscan2
- ARSA | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 43/365 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs142142638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASB2 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 40/383 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as rs944011813, COSV73636374; called by muse, mutect2, varscan2
- ASB3 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs757255593, COSV55075572; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 34/214 reads (16%) | catalogued as rs747570359; called by mutect2, varscan2
- ASIC3 | c.77T>C p.M26T | Missense Mutation (SNP) | VAF 63/512 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs1346910748; called by muse, mutect2, varscan2
- ASIC4 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV61731083; called by muse, mutect2, varscan2
- ASPG | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 46/336 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs532981359, COSV71933792; called by muse, mutect2, varscan2
- ASPHD2 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 50/362 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53219863, COSV99313203; called by muse, mutect2, varscan2
- ASPM | c.9187A>G p.I3063V | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs1406859691; called by muse, mutect2, varscan2
- ASPM | c.6961T>C p.S2321P | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.349); catalogued as COSV54136947; called by muse, mutect2, varscan2
- ASPRV1 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 52/355 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs149847323; called by muse, mutect2, varscan2
- ATF4 | c.406del p.Q136Rfs*3 | Frame Shift Del (DEL) | VAF 39/248 reads (16%) | catalogued as rs770192882; called by mutect2, pindel, varscan2
- ATG4B | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs745809380, COSV60350155; called by muse, mutect2, varscan2
- ATP1A3 | c.2828G>A p.R943Q (on ENST00000545399 / NM_001256214.2; = p.R930Q on NM_152296.5) | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57486874; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1101del p.T368Lfs*43 | Frame Shift Del (DEL) | VAF 44/314 reads (14%) | catalogued as rs760459265; called by mutect2, pindel, varscan2
- ATXN1L | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.572); catalogued as rs904895544, COSV101449147; called by muse, mutect2
- AVEN | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1166233623; called by muse, mutect2
- AWAT2 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs774238083; called by muse, mutect2, varscan2
- B3GALT4 | c.919_920del p.Q307Vfs*43 | Frame Shift Del (DEL) | VAF 50/460 reads (11%) | catalogued as rs1273335239; called by pindel, varscan2
- B3GALT6 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 50/435 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV55419798; called by muse, mutect2, varscan2
- B3GNT10 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 23/289 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as rs183371382; called by muse, mutect2
- B3GNT3 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs560672467; called by muse, mutect2
- B4GALNT1 | c.1348G>A p.G450S | Missense Mutation (SNP) | VAF 28/313 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100246880; called by muse, mutect2
- B4GALNT4 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777075662, COSV57323066; called by muse, mutect2, varscan2
- B4GALNT4 | c.2819C>T p.A940V | Missense Mutation (SNP) | VAF 38/397 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs754695703, COSV57324785; called by muse, mutect2
- BACE1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 46/424 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs780780315; called by muse, mutect2, varscan2
- BACH1 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 44/301 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250115670; called by muse, mutect2, varscan2
- BCAN | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 49/381 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs755318164; called by muse, mutect2, varscan2
- BIRC6 | c.11065T>C p.F3689L | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1295152947; called by muse, mutect2, varscan2
- BMERB1 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as COSV55507141; called by muse, mutect2, varscan2
- BMP1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 57/408 reads (14%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.315); catalogued as rs866875012; called by muse, mutect2, varscan2
- BNC2 | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV101032504; called by muse, mutect2
- BOLA1 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 56/404 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as rs782118083; called by muse, varscan2
- BOP1 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 41/510 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs887095055; called by muse, mutect2
- BPTF | c.3245G>A p.R1082Q | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs764527892, COSV58833907; called by muse, mutect2, varscan2
- BRAF | c.1862A>T p.N621I (on ENST00000288602 / NM_001374244.1; = p.N581I on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV56058108, COSV56106422, COSV56110832; called by muse, mutect2, varscan2
- BRAT1 | c.1480A>G p.I494V | Missense Mutation (SNP) | VAF 40/372 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV61397259; called by muse, mutect2, varscan2
- BRF1 | c.1900G>A p.V634M | Missense Mutation (SNP) | VAF 45/365 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as rs777504331, COSV59267810; called by muse, mutect2, varscan2
- BRINP3 | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 24/294 reads (8%) | catalogued as COSV100818702, COSV66515003; called by muse, mutect2
- BRINP3 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 27/329 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1353622451; called by muse, mutect2
- BRPF1 | c.2830C>T p.R944W | Missense Mutation (SNP) | VAF 46/429 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs748786588, COSV100121062; called by muse, mutect2, varscan2
- BSG | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 20/488 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1332040865, COSV61076146; called by muse, mutect2
- BTK | c.1427A>G p.Y476C | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as CD146574; called by muse, mutect2, varscan2
- BTN3A1 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs780278847, COSV50024575; called by muse, mutect2
- BX255925.3 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 41/374 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs377080924; called by muse, mutect2, varscan2
- C11orf87 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 46/362 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.96); catalogued as COSV100535802; called by muse, mutect2, varscan2
- C17orf107 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 59/485 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.022); catalogued as rs1481573378; called by muse, mutect2, varscan2
- C17orf97 | c.359G>T p.R120M | Missense Mutation (SNP) | VAF 30/291 reads (10%) | catalogued as rs1296310540; called by muse, mutect2
- C18orf54 | c.85A>G p.S29G | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1293056762; called by muse, mutect2, varscan2
- C1QB | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 37/312 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1453569731, COSV100152814; called by muse, mutect2, varscan2
- C1QL1 | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 43/280 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs370315808; called by muse, mutect2, varscan2
- C1orf158 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs764070915; called by muse, mutect2, varscan2
- C1orf54 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as rs782516643, COSV51743235; called by muse, mutect2, varscan2
- C1orf87 | c.454A>G p.M152V | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as rs200544216; called by muse, mutect2, varscan2
- C20orf27 | c.418G>A p.V140I (on ENST00000379772 / NM_001258429.2; = p.V165I on NM_001039140.3) | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.286); catalogued as rs771545812; called by muse, mutect2, varscan2
- C3 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.148); catalogued as rs766880159, COSV99835780; called by muse, mutect2, varscan2
- C3AR1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs371493019; called by muse, mutect2, varscan2
- C6orf132 | c.1344del p.S449Afs*68 | Frame Shift Del (DEL) | VAF 34/212 reads (16%) | catalogued as rs774701362; called by mutect2, pindel, varscan2
- C6orf136 | c.763C>T p.R255W (on ENST00000376473 / NM_001109938.3; = p.R121W on NM_145029.4) | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289606411, COSV99527841; called by muse, mutect2, varscan2
- C7 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs774733206; called by muse, mutect2
- C7orf25 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 36/291 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1278985739, COSV63273555; called by muse, mutect2, varscan2
- CACNA1E | c.2758C>T p.R920C | Missense Mutation (SNP) | VAF 57/312 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as rs769232172, COSV100702048, COSV62382687; called by muse, mutect2, varscan2
- CACNA2D3 | c.384T>C p.Y128= | Splice Region (SNP) | VAF 21/153 reads (14%) | catalogued as rs887815890; called by muse, mutect2, varscan2
- CACNB1 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 33/362 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV59998707; called by muse, mutect2
- CADPS | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 46/347 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as rs150415917; called by muse, mutect2, varscan2
- CAMK2G | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs574663899; called by muse, mutect2, varscan2
- CAPN12 | c.1225del p.A409Lfs*30 | Frame Shift Del (DEL) | VAF 27/176 reads (15%) | catalogued as rs1341489183; called by mutect2, pindel, varscan2
- CAPN13 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54429443; called by muse, mutect2, varscan2
- CAPN15 | c.2833del p.V945Wfs*29 | Frame Shift Del (DEL) | VAF 36/304 reads (12%) | catalogued as COSV54836525; called by mutect2, pindel, varscan2
- CARNS1 | c.517G>T p.G173W | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57129968; called by muse, mutect2
- CASZ1 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 45/376 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.014); catalogued as rs1412420306, COSV100680497; called by muse, varscan2
- CATSPER4 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 42/353 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1212188634; called by muse, mutect2, varscan2
- CATSPERD | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as rs373865922; called by muse, mutect2, varscan2
- CC2D1A | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 53/366 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760036269; called by muse, mutect2, varscan2
- CC2D2A | c.4616_4618del p.G1539del | In Frame Del (DEL) | VAF 38/256 reads (15%) | catalogued as rs1267184899; called by mutect2, pindel, varscan2
- CCDC149 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760088417; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 36/130 reads (28%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 18/118 reads (15%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC27 | c.1915del p.L639Cfs*8 | Frame Shift Del (DEL) | VAF 34/232 reads (15%) | catalogued as rs751021664; called by mutect2, pindel, varscan2
- CCDC40 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs185083705, COSV53899963; called by muse, mutect2
- CCDC69 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1158560432; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC88C | c.5311G>A p.A1771T | Missense Mutation (SNP) | VAF 45/407 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as rs906039833; called by muse, mutect2, varscan2
- CCNF | c.1866G>T p.E622D | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1233772088; called by muse, mutect2
- CCPG1 | c.2062G>A p.G688S | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as rs781261494; called by muse, mutect2, varscan2
- CCT7 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.964); catalogued as rs373577960; called by muse, mutect2, varscan2
- CCT8L2 | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 44/295 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as rs1298168502; called by muse, mutect2, varscan2
- CD81 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.886); catalogued as COSV99719261; called by muse, mutect2, varscan2
- CD8B | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.173); catalogued as rs1446544258; called by muse, mutect2, varscan2
- CDH22 | c.1900G>A p.V634I | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs749043438, COSV64836992; called by muse, mutect2, varscan2
- CDH23 | c.9866C>T p.T3289M | Missense Mutation (SNP) | VAF 57/362 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as rs922748358; called by muse, mutect2, varscan2
- CDK5R2 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 44/382 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1274075541; called by muse, varscan2
- CDT1 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs758722232, COSV99967380; called by muse, mutect2, varscan2
- CDYL | c.607G>A p.V203I (on ENST00000328908 / NM_001368125.1; = p.V149I on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/339 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs371998448, COSV59359380; called by muse, mutect2, varscan2
- CELSR1 | c.3811C>T p.R1271C | Missense Mutation (SNP) | VAF 53/392 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs531245611, COSV99418325; called by muse, varscan2
- CELSR1 | c.486del p.R163Gfs*81 | Frame Shift Del (DEL) | VAF 25/191 reads (13%) | catalogued as rs1396624679; called by mutect2, pindel, varscan2
- CEMIP | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775636535; called by muse, mutect2, varscan2
- CEMIP | c.2356G>A p.A786T | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV54988352; called by muse, mutect2
- CENATAC | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 34/297 reads (11%) | catalogued as rs367702790; called by muse, mutect2, varscan2
- CEP350 | c.6765del p.K2255Nfs*4 | Frame Shift Del (DEL) | VAF 12/111 reads (11%) | catalogued as COSV100854595; called by mutect2, pindel, varscan2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 24/209 reads (11%) | catalogued as rs747835123, COSV61504174; called by mutect2, pindel
- CFAP61 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 47/383 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs765242746; called by muse, mutect2, varscan2
- CFAP92 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.225); catalogued as rs754077147; called by muse, mutect2
- CHDH | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1158325881; called by muse, mutect2
- CHRNB2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as rs774455462; called by muse, mutect2, varscan2
- CHST10 | c.275G>A p.C92Y | Missense Mutation (SNP) | VAF 26/291 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51804392; called by muse, mutect2
- CHST3 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 51/367 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766145797; called by muse, mutect2, varscan2
- CHST5 | c.190C>T p.H64Y | Missense Mutation (SNP) | VAF 49/388 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774900874, COSV60337086; called by muse, mutect2, varscan2
- CILP2 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 42/338 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs1201457889; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 21/139 reads (15%) | catalogued as rs752250702; called by mutect2, varscan2
- CLIC6 | c.1613C>T p.T538M (on ENST00000360731 / NM_001317009.2; = p.T520M on NM_053277.3) | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs374436284; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 24/112 reads (21%) | catalogued as rs369752219; called by mutect2, varscan2
- CLPP | c.28del p.A10Pfs*117 | Frame Shift Del (DEL) | VAF 26/240 reads (11%) | catalogued as rs770403079; called by mutect2, pindel, varscan2
- CMYA5 | c.8669G>A p.S2890N | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV101484470; called by muse, mutect2, varscan2
- CNBD1 | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV72976014; called by muse, mutect2, varscan2
- CNDP1 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs200821231; called by muse, mutect2
- CNKSR1 | c.1535del p.P512Hfs*58 (on ENST00000374253 / NM_001297647.2; = p.P505Hfs*58 on NM_006314.3) | Frame Shift Del (DEL) | VAF 26/194 reads (13%) | catalogued as rs753922055; called by mutect2, varscan2
- CNOT4 | c.1235G>A p.R412Q (on ENST00000315544 / NM_001190848.1; = p.R409Q on NM_013316.4) | Missense Mutation (SNP) | VAF 42/352 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.361); catalogued as rs376005439, COSV59657725; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 24/263 reads (9%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel
- CNTRL | c.6739C>T p.R2247* | Nonsense Mutation (SNP) | VAF 22/318 reads (7%) | catalogued as rs149831066, COSV53053418; called by muse, mutect2
- COG8 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 62/315 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766352349; called by muse, mutect2, varscan2
- COL18A1 | c.2800G>A p.A934T (on ENST00000359759 / NM_130444.3; = p.A699T on NM_030582.4) | Missense Mutation (SNP) | VAF 49/399 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.649); catalogued as rs61737706, COSV62704404; called by muse, mutect2, varscan2
- COL18A1 | c.3279G>A p.G1093= (on ENST00000359759 / NM_130444.3; = p.G858= on NM_030582.4) | Splice Region (SNP) | VAF 40/272 reads (15%) | catalogued as rs375058430; called by muse, mutect2, varscan2
- COL6A3 | c.4064C>T p.P1355L | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs140863092, COSV99801569; called by muse, mutect2, varscan2
- CORO1A | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 47/438 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs761769549; called by muse, mutect2, varscan2
- CPEB4 | c.268C>A p.P90T | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1238095505; called by mutect2, varscan2
- CPSF1 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 41/345 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as rs782215456; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 24/225 reads (11%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRACD | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 35/370 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51715593; called by muse, mutect2
- CREBBP | c.5302C>T p.R1768C | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99268435; called by muse, mutect2, varscan2
- CSMD1 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs573237339, COSV68198917; called by muse, varscan2
- CSMD2 | c.6506G>A p.R2169Q | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1020168867; called by muse, mutect2, varscan2
- CSNK1A1L | c.690dup p.Q231Tfs*4 | Frame Shift Ins (INS) | VAF 30/230 reads (13%) | catalogued as rs369743261; called by mutect2, varscan2
- CYP3A7-CYP3A51P | c.1573dup p.W525Lfs*? | Frame Shift Ins (INS) | VAF 24/186 reads (13%) | catalogued as rs778264050; called by mutect2, varscan2
- CYP7B1 | c.392del p.N131Ifs*4 | Frame Shift Del (DEL) | VAF 20/190 reads (11%) | catalogued as rs748480664, COSV59597772; called by mutect2, pindel
- DAB2IP | c.830G>A p.R277Q (on ENST00000408936; = p.R249Q on NM_032552.3) | Missense Mutation (SNP) | VAF 61/408 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs1422475960; called by muse, mutect2, varscan2
- DAO | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1339389202; called by muse, mutect2, varscan2
- DCAF12L2 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1254668948, COSV63583106; called by muse, mutect2, varscan2
- DCANP1 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 41/394 reads (10%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs376193776; called by muse, mutect2, varscan2
- DCHS1 | c.6199C>T p.R2067C | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368032944, COSV100202199; called by muse, mutect2, varscan2
- DCN | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.77); catalogued as rs148769847; called by muse, mutect2, varscan2
- DCST2 | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs373083804; called by muse, mutect2, varscan2
- DDC | c.1013A>C p.Q338P | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV63563574; called by muse, mutect2
- DDN | c.419del p.P140Rfs*70 | Frame Shift Del (DEL) | VAF 45/375 reads (12%) | catalogued as COSV60293086; called by mutect2, pindel, varscan2
- DDR1 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 35/582 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749362174; called by muse, mutect2
- DDX31 | c.2440C>T p.R814W | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs776536280; called by muse, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 27/84 reads (32%) | catalogued as rs772416332; called by mutect2, varscan2
- DENND5A | c.2684del p.K895Sfs*7 | Frame Shift Del (DEL) | VAF 24/204 reads (12%) | catalogued as rs1208100549; called by pindel, varscan2
- DHCR7 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs370307688, CM154233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHH | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372019612; called by muse, mutect2, varscan2
- DHX30 | c.548G>A p.R183H (on ENST00000445061 / NM_138615.3; = p.R144H on NM_014966.3) | Missense Mutation (SNP) | VAF 36/337 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.152); catalogued as rs777783057; called by muse, mutect2, varscan2
- DHX57 | c.3115C>T p.R1039* | Nonsense Mutation (SNP) | VAF 49/327 reads (15%) | catalogued as rs1450774084, COSV99769988; called by muse, mutect2, varscan2
- DIAPH3 | c.3055del p.R1019Efs*12 (on ENST00000400324 / NM_001042517.2; = p.R756Efs*12 on NM_030932.3) | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | catalogued as rs753024929; called by mutect2, pindel
- DIP2C | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.523); catalogued as rs368102774; called by muse, mutect2, varscan2
- DKK1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 41/316 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.415); catalogued as rs777749212; called by muse, mutect2, varscan2
- DLG4 | c.1363C>T p.R455C (on ENST00000399506 / NM_001321075.3; = p.R498C on NM_001365.4) | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs1207600580, COSV57237235; called by muse, mutect2, varscan2
- DLGAP1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs530636110; called by muse, mutect2, varscan2
- DLGAP2 | c.393del p.R132Afs*15 | Frame Shift Del (DEL) | VAF 49/475 reads (10%) | catalogued as rs755665055, COSV101422687, COSV70099967; called by pindel, varscan2*
- DLGAP3 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.764); catalogued as rs1159145122; called by muse, varscan2
- DLGAP3 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 40/344 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs760752627, COSV52396211; called by muse, varscan2
- DLGAP4 | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs748316867; called by muse, mutect2, varscan2
- DMRT2 | c.105del p.S38Afs*80 | Frame Shift Del (DEL) | VAF 42/392 reads (11%) | catalogued as rs1234829240; called by mutect2, pindel
- DMRT3 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV51906416; called by muse, mutect2, varscan2
- DMXL1 | c.5004del p.F1668Lfs*15 | Frame Shift Del (DEL) | VAF 26/177 reads (15%) | catalogued as rs770333963; called by mutect2, pindel, varscan2
- DNAH1 | c.7423G>A p.V2475M | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370585761; called by muse, mutect2, varscan2
- DNAH2 | c.12815G>A p.R4272Q | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs1182032019, COSV101208932; called by muse, mutect2, varscan2
- DNAH5 | c.12379C>T p.R4127C | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148696723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNASE1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1251078795; called by muse, mutect2, varscan2
- DNHD1 | c.13402G>A p.A4468T | Missense Mutation (SNP) | VAF 46/383 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as rs750867659, COSV54430612; called by muse, mutect2, varscan2
- DNM3 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62458164; called by muse, mutect2, varscan2
- DOCK1 | c.3526C>T p.R1176C | Missense Mutation (SNP) | VAF 41/347 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); catalogued as rs778147174, COSV99730581; called by muse, mutect2, varscan2
- DOCK2 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 48/287 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as rs764590955, COSV99913952; called by muse, mutect2, varscan2
- DOCK4 | c.4151C>A p.A1384D | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV70240556; called by muse, mutect2
- DOT1L | c.3215G>A p.R1072H | Missense Mutation (SNP) | VAF 41/420 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.996); catalogued as rs777184095; called by muse, mutect2, varscan2
- DPP7 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.383); catalogued as rs777004339, COSV100857374; called by muse, mutect2, varscan2
- DPP7 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 46/363 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.083); catalogued as rs1282239037; called by muse, mutect2, varscan2
- DUS3L | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 52/406 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1285209820; called by muse, mutect2, varscan2
- DXO | c.611dup p.D205Rfs*7 | Frame Shift Ins (INS) | VAF 26/264 reads (10%) | catalogued as rs762105628; called by mutect2, pindel
- DYNC1H1 | c.5293G>A p.A1765T | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as rs144147463; ClinVar: uncertain significance; called by mutect2, varscan2
- EEF1G | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs761237813; called by muse, mutect2, varscan2
- EFCAB13 | c.1179dup p.H394Tfs*6 | Frame Shift Ins (INS) | VAF 23/180 reads (13%) | catalogued as rs1358875923; called by mutect2, pindel, varscan2
- EFR3A | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 32/304 reads (11%) | catalogued as rs769584711, COSV54459896; called by muse, mutect2
- EHMT1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as rs373269573; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- EIF5B | c.149del p.K50Sfs*10 | Frame Shift Del (DEL) | VAF 24/159 reads (15%) | catalogued as rs749961066, COSV56813566; called by mutect2, varscan2
- ELK1 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs376525319; called by muse, mutect2, varscan2
- ELK3 | c.525dup p.V176Rfs*14 | Frame Shift Ins (INS) | VAF 42/314 reads (13%) | catalogued as rs769175197; called by mutect2, varscan2
- ELOA2 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 52/392 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as rs151198704; called by muse, mutect2, varscan2
- EMILIN1 | c.1353del p.L452Cfs*5 | Frame Shift Del (DEL) | VAF 39/267 reads (15%) | catalogued as COSV53155402; called by mutect2, pindel, varscan2
- EML4 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1193492729, COSV100580677; called by muse, mutect2, varscan2
- EPHB1 | c.1203del p.Y402Tfs*46 | Frame Shift Del (DEL) | VAF 36/273 reads (13%) | catalogued as COSV101213134; called by mutect2, pindel, varscan2
- EPHB4 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs139594739; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 53/344 reads (15%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- ERI3 | c.75del p.A26Pfs*43 | Frame Shift Del (DEL) | VAF 40/298 reads (13%) | catalogued as rs1296485121, COSV64833152; called by pindel, varscan2
- ERMN | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 46/308 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs1351809810; called by muse, mutect2, varscan2
- ERRFI1 | c.855del p.R286Efs*9 | Frame Shift Del (DEL) | VAF 26/240 reads (11%) | catalogued as rs1557463619; called by mutect2, pindel
- ERVMER34-1 | c.899del p.L300Cfs*33 | Frame Shift Del (DEL) | VAF 32/256 reads (13%) | catalogued as rs779855268; called by mutect2, varscan2
- ESF1 | c.512del p.N171Tfs*18 | Frame Shift Del (DEL) | VAF 20/165 reads (12%) | catalogued as rs745713173; called by mutect2, varscan2
- ESPN | c.1750G>A p.G584S | Missense Mutation (SNP) | VAF 39/354 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.336); catalogued as rs1258567728; called by muse, mutect2, varscan2
- ESPNL | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 21/492 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1044194444, COSV58032070; called by muse, mutect2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 36/292 reads (12%) | catalogued as rs775950025; called by mutect2, varscan2
- F10 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 45/339 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121964947, CM000377, COSV65020885; called by muse, mutect2, varscan2
- F2 | c.1501del p.V501* | Frame Shift Del (DEL) | VAF 22/229 reads (10%) | catalogued as CM034520; called by mutect2, varscan2
- FAM104A | c.268dup p.Q90Pfs*6 | Frame Shift Ins (INS) | VAF 24/210 reads (11%) | catalogued as rs769947396; called by mutect2, varscan2
- FAM120A | c.2360G>A p.C787Y | Missense Mutation (SNP) | VAF 56/338 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52911217; called by muse, mutect2, varscan2
- FAM124B | c.382del p.V128* | Frame Shift Del (DEL) | VAF 48/350 reads (14%) | catalogued as COSV66271694; called by mutect2, varscan2
- FAM135A | c.4154C>T p.S1385L (on ENST00000370479 / NM_001351599.1; = p.S1172L on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376113434, COSV99525380; called by muse, mutect2
- FAM135B | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 24/319 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.065); catalogued as rs369404911, COSV50523175; called by muse, mutect2
- FAM155A | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 70/468 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV65575991; called by muse, varscan2
- FAM168B | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs1358356358, COSV101112206; called by muse, mutect2
- FAM171A1 | c.2459C>T p.S820L | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1369563832, COSV65321039; called by muse, mutect2, varscan2
- FAM184B | c.2023C>T p.H675Y | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as rs1231942763; called by muse, mutect2
- FAM205A | c.3944C>T p.P1315L | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs546555671; called by muse, mutect2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 49/449 reads (11%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAS | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV58239617, COSV58240502; called by muse, mutect2
- FAT2 | c.12907A>G p.S4303G | Missense Mutation (SNP) | VAF 47/391 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1455822700; called by muse, mutect2, varscan2
- FBXL6 | c.834G>A p.W278* | Nonsense Mutation (SNP) | VAF 47/347 reads (14%) | catalogued as rs1554852949, COSV57352849; called by muse, mutect2, varscan2
- FBXL7 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs776522515, COSV61642885; called by muse, mutect2, varscan2
- FBXO30 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs775796081; called by muse, mutect2, varscan2
- FBXW10 | c.872-4C>T | Splice Region (SNP) | VAF 28/316 reads (9%) | catalogued as COSV57316047; called by mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 15/93 reads (16%) | catalogued as rs768979093, COSV55110370; called by mutect2, pindel, varscan2
- FER1L6 | c.1406dup p.E470Gfs*8 | Frame Shift Ins (INS) | VAF 21/171 reads (12%) | catalogued as rs950533888; called by mutect2, pindel, varscan2
- FGF20 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 29/279 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as rs1236847607; called by muse, mutect2, varscan2
- FIGNL2 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 41/402 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs1326989600; called by muse, mutect2, varscan2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/228 reads (11%) | catalogued as COSV58769165; called by mutect2, varscan2
- FKBP6 | c.348C>A p.Y116* | Nonsense Mutation (SNP) | VAF 39/335 reads (12%) | catalogued as COSV52722262; called by muse, mutect2, varscan2
- FKRP | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 41/360 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1221347765; called by muse, mutect2, varscan2
- FLNA | c.5488G>A p.V1830M (on ENST00000369850 / NM_001110556.2; = p.V1822M on NM_001456.3) | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs782505945, COSV61037963; called by muse, mutect2, varscan2
- FLRT1 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 46/362 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.77); catalogued as COSV55359361; called by muse, mutect2, varscan2
- FLRT2 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 43/307 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV58142651; called by muse, mutect2, varscan2
- FLT4 | c.3137C>T p.S1046L | Missense Mutation (SNP) | VAF 25/314 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1460237997, COSV56097615; called by muse, mutect2
- FLT4 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 48/319 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs933223149, COSV56100930; called by muse, mutect2, varscan2
- FN3K | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 39/322 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs780773026, COSV56181226; called by muse, mutect2, varscan2
- FOXD2 | c.268del p.A90Rfs*37 | Frame Shift Del (DEL) | VAF 10/83 reads (12%) | catalogued as rs1204362076; called by mutect2, pindel, varscan2
- FOXK2 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100081716, COSV58879261; called by muse, mutect2, varscan2
- FOXK2 | c.1871C>T p.P624L | Missense Mutation (SNP) | VAF 41/336 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs764593468; called by muse, mutect2, varscan2
- FPR1 | c.884G>A p.C295Y | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1312853445, COSV59051228; called by muse, mutect2, varscan2
- FREM2 | c.8159del p.P2720Qfs*48 | Frame Shift Del (DEL) | VAF 18/165 reads (11%) | catalogued as rs967339760, COSV54850967; called by mutect2, pindel, varscan2
- FSTL4 | c.727+1G>A p.X243_splice | Splice Site (SNP) | VAF 18/207 reads (9%) | catalogued as rs1039239148; called by muse, mutect2
- FUZ | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as rs770626233, COSV58241599; called by muse, mutect2, varscan2
- FZD2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867681109, COSV59528501; called by muse, mutect2, varscan2
- FZD6 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); catalogued as rs767273753, CM120932; called by muse, mutect2, varscan2
- GAL3ST1 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 52/384 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1388848996; called by muse, mutect2, varscan2
- GALR3 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs8137748; called by muse, mutect2, varscan2
- GATAD2A | c.1246A>G p.M416V | Missense Mutation (SNP) | VAF 42/305 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1247251455; called by muse, mutect2, varscan2
- GCK | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 36/486 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.237); catalogued as CM149036, COSV99789873; called by muse, mutect2
- GCM2 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 51/370 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200953294, COSV65275071; called by muse, mutect2, varscan2
- GDF6 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749537908, COSV54629041; called by muse, mutect2, varscan2
- GGTLC1 | c.279dup p.S94Lfs*57 | Frame Shift Ins (INS) | VAF 29/194 reads (15%) | catalogued as rs753146433; called by mutect2, pindel, varscan2
- GID8 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs762677628, COSV99824210; called by muse, mutect2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 36/273 reads (13%) | catalogued as rs763147690; called by mutect2, varscan2
- GIMAP1 | c.851del p.G284Afs*39 | Frame Shift Del (DEL) | VAF 43/406 reads (11%) | catalogued as rs756722011, COSV100212336; called by mutect2, pindel, varscan2
- GJD4 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 24/389 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564470781; called by muse, mutect2
- GLIS1 | c.344del p.G115Afs*31 | Frame Shift Del (DEL) | VAF 45/332 reads (14%) | catalogued as COSV100389202; called by mutect2, pindel, varscan2
- GLIS2 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 68/488 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as rs555198215; called by muse, mutect2, varscan2
- GMDS | c.1087G>A p.V363M | Missense Mutation (SNP) | VAF 40/330 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); catalogued as rs149819971; called by muse, mutect2, varscan2
- GNL3L | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV60576205; called by muse, mutect2, varscan2
- GON4L | c.3031T>C p.S1011P | Missense Mutation (SNP) | VAF 46/388 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); catalogued as rs559977466; called by muse, mutect2, varscan2
- GPD2 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 38/315 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs771535457; called by muse, mutect2, varscan2
- GPR135 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs773396462; called by muse, mutect2, varscan2
- GPR143 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs199899645, CM074258, COSV66632424; called by muse, mutect2, varscan2
- GPR27 | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 77/454 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs745750974; called by muse, mutect2, varscan2
- GPR3 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 47/398 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs911214961; called by muse, mutect2, varscan2
- GPX5 | c.395T>C p.F132S | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69079653; called by muse, mutect2, varscan2
- GRIK1 | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs765040687; called by muse, mutect2, varscan2
- GRIK2 | c.1741A>G p.I581V | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.897); catalogued as rs1554281005; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIN2B | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 42/323 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370809599, COSV99078317; called by muse, varscan2
- GRM3 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); catalogued as COSV100862887; called by muse, mutect2
- GRM4 | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 44/375 reads (12%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs148197470; called by muse, mutect2, varscan2
- GRM6 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 44/403 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as rs771522860; called by muse, mutect2, varscan2
- GRM7 | c.2427del p.F809Lfs*21 | Frame Shift Del (DEL) | VAF 22/158 reads (14%) | catalogued as rs747773579; called by mutect2, varscan2
- GRM8 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 39/354 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767201811, COSV58802360; called by muse, mutect2, varscan2
- GSTA1 | c.283T>C p.Y95H | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs577327388; called by muse, mutect2, varscan2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 32/225 reads (14%) | catalogued as rs1231771183; called by mutect2, pindel, varscan2
- GXYLT2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765570985; called by muse, mutect2, varscan2
- GZF1 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs780925612, COSV57637434; called by muse, mutect2
- GZMM | c.43del p.A15Pfs*4 | Frame Shift Del (DEL) | VAF 43/283 reads (15%) | catalogued as rs1260022730; called by mutect2, pindel, varscan2
- HACL1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751521527; called by muse, mutect2
- HAGHL | c.640del p.E214Rfs*15 | Frame Shift Del (DEL) | VAF 29/105 reads (28%) | catalogued as rs747918697; called by mutect2, varscan2
- HAVCR2 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759158630, COSV57152127; called by muse, mutect2, varscan2
- HDAC3 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59495491; called by muse, mutect2, varscan2
- HDX | c.1718A>G p.H573R | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs372685978; called by muse, mutect2, varscan2
- HEATR1 | c.2386T>A p.F796I | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as rs746366377, COSV100857657; called by muse, mutect2, varscan2
- HECA | c.1321A>G p.M441V | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); catalogued as rs1162045741; called by muse, mutect2, varscan2
- HECTD2 | c.2251C>T p.P751S | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53220620; called by muse, mutect2, varscan2
- HERC2 | c.7564G>A p.E2522K | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.114); catalogued as rs758021444; called by muse, mutect2
- HERC2 | c.6124G>A p.A2042T | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs202046283; called by muse, mutect2, varscan2
- HIC1 | c.1172G>A p.G391D (on ENST00000322941 / NM_001098202.1; = p.G372D on NM_006497.4) | Missense Mutation (SNP) | VAF 52/308 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.047); catalogued as COSV99558145; called by muse, varscan2
- HIPK2 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs767985572; called by muse, mutect2, varscan2
- HLA-DPB1 | c.31dup p.R11Pfs*38 | Frame Shift Ins (INS) | VAF 44/310 reads (14%) | catalogued as rs1048293876; called by mutect2, pindel, varscan2
- HLX | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 47/433 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as rs747201663; called by muse, mutect2, varscan2
- HOXA13 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 55/423 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1281379285; called by muse, mutect2, varscan2
- HSPA6 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs763048231, COSV59060126; called by muse, mutect2, varscan2
- IFT140 | c.2885C>T p.A962V | Missense Mutation (SNP) | VAF 44/350 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1371411242, COSV54154500; called by muse, mutect2
- IFT140 | c.2138G>A p.R713Q | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs200440483; called by muse, varscan2
- IGFBP3 | c.95del p.A32Gfs*40 | Frame Shift Del (DEL) | VAF 39/262 reads (15%) | catalogued as CM057457; called by mutect2, pindel, varscan2
- IGFBP7 | c.498del p.K167Rfs*13 | Frame Shift Del (DEL) | VAF 32/214 reads (15%) | catalogued as rs765398170; called by mutect2, pindel, varscan2
- IGFN1 | c.3491G>A p.R1164Q (on ENST00000295591 / NM_001367841.1; = p.R3621Q on NM_001164586.2) | Missense Mutation (SNP) | VAF 45/392 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs371094909; called by muse, mutect2, varscan2
- IGHV1-3 | c.17G>T p.R6M | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs561032078; called by muse, mutect2, varscan2
- IGHV3OR16-9 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 39/430 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs4026455; called by muse, mutect2, varscan2
- IGSF3 | c.2527C>T p.R843C (on ENST00000369486 / NM_001007237.3; = p.R863C on NM_001542.4) | Missense Mutation (SNP) | VAF 36/343 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774807591, COSV100604803; called by muse, mutect2, varscan2
- IGSF9B | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs971906069; called by muse, mutect2, varscan2
- IGSF9B | c.439dup p.Q147Pfs*10 | Frame Shift Ins (INS) | VAF 26/192 reads (14%) | catalogued as rs748943611; called by mutect2, varscan2
- IL11 | c.540dup p.L181Afs*6 | Frame Shift Ins (INS) | VAF 50/402 reads (12%) | catalogued as rs768878885; called by mutect2, varscan2
- IL17RD | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 29/264 reads (11%) | catalogued as COSV56337824; called by muse, mutect2, varscan2
- IL17REL | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 60/439 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.533); catalogued as rs535702206, COSV100377466; called by muse, mutect2, varscan2
- IL1RAP | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201706120, COSV50762742; called by muse, mutect2
- IL4 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as rs539263445; called by muse, mutect2, varscan2
- INHBA | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 42/398 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV54219478, COSV54221719; called by muse, mutect2, varscan2
- INPP5F | c.2417_2418del p.F806Yfs*4 | Frame Shift Del (DEL) | VAF 19/195 reads (10%) | catalogued as rs766615960; called by mutect2, pindel, varscan2
- INSM2 | c.165del p.T56Pfs*9 | Frame Shift Del (DEL) | VAF 39/383 reads (10%) | catalogued as rs1306209110; called by mutect2, pindel, varscan2
- INTS1 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1368556754; called by muse, mutect2, varscan2
- INTS9 | c.1723G>A p.V575I | Missense Mutation (SNP) | VAF 41/383 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs537896246, COSV68433137; called by muse, mutect2, varscan2
- INTU | c.395del p.N132Ifs*11 | Frame Shift Del (DEL) | VAF 22/182 reads (12%) | catalogued as rs771175764; called by mutect2, varscan2
- INVS | c.1117G>A p.V373M | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759162487, COSV52440067; called by muse, mutect2, varscan2
- IRX1 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 34/295 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs777288883, COSV57360192; called by muse, mutect2, varscan2
- IRX3 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 52/419 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1490846942; called by muse, varscan2
- IRX4 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 50/455 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51471463; called by muse, mutect2, varscan2
- ISYNA1 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs778814250; called by muse, mutect2, varscan2
- ITCH | c.1211G>A p.R404H (on ENST00000262650 / NM_001257137.3; = p.R363H on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/333 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs764257608; ClinVar: uncertain significance; called by muse, varscan2
- ITGA5 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 46/381 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.503); catalogued as rs375602887; called by muse, mutect2, varscan2
- ITGAL | c.1048T>C p.S350P | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63324944; called by muse, mutect2, varscan2
- ITGAM | c.1441del p.H481Ifs*45 (on ENST00000648685 / NM_001145808.2; = p.H481Ifs*44 on NM_000632.4) | Frame Shift Del (DEL) | VAF 48/434 reads (11%) | catalogued as rs1303173835; called by mutect2, pindel, varscan2
- JHY | c.841dup p.R281Kfs*35 | Frame Shift Ins (INS) | VAF 24/197 reads (12%) | catalogued as rs974240509; called by mutect2, varscan2
- JMJD1C | c.6075del p.E2026Kfs*45 | Frame Shift Del (DEL) | VAF 16/142 reads (11%) | catalogued as rs1226801045; called by mutect2, varscan2
- JPH3 | c.1060del p.L354Cfs*117 | Frame Shift Del (DEL) | VAF 34/330 reads (10%) | catalogued as COSV52470301; called by mutect2, pindel
- KBTBD7 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 45/333 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs780667713, COSV65266474; called by muse, mutect2, varscan2
- KCNC2 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs199735865, COSV54374815; called by muse, mutect2
- KCNK4 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 59/485 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs778403926; called by muse, mutect2, varscan2
- KCTD16 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.175); catalogued as rs1224202448, COSV72576801; called by muse, mutect2, varscan2
- KCTD3 | c.2416del p.S806Vfs*16 | Frame Shift Del (DEL) | VAF 38/292 reads (13%) | catalogued as rs754600318; called by mutect2, pindel, varscan2
- KDM4B | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 59/370 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs143993914; called by muse, mutect2, varscan2
- KDM4C | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 40/384 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV67183405; called by muse, varscan2
- KDR | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); catalogued as rs147066083, COSV55775582; called by muse, mutect2, varscan2
- KIAA0232 | c.2353del p.T785Hfs*4 | Frame Shift Del (DEL) | VAF 16/145 reads (11%) | catalogued as rs1560202607; called by mutect2, pindel, varscan2
- KIAA1614 | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs374332282; called by muse, mutect2, varscan2
- KIAA2026 | c.2187del p.A730Qfs*26 | Frame Shift Del (DEL) | VAF 34/170 reads (20%) | catalogued as rs749990720; called by mutect2, varscan2
- KIF14 | c.2986del p.M996Cfs*4 | Frame Shift Del (DEL) | VAF 20/145 reads (14%) | catalogued as rs1164624349; called by mutect2, varscan2
- KIF16B | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1478305353, COSV61705892; called by muse, mutect2, varscan2
- KIF26B | c.3859G>A p.A1287T | Missense Mutation (SNP) | VAF 43/419 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV63636922; called by muse, mutect2, varscan2
- KIFC3 | c.1310A>G p.N437S | Missense Mutation (SNP) | VAF 40/289 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs781953652; called by muse, mutect2, varscan2
- KIRREL2 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.664); catalogued as rs745966676; called by muse, mutect2, varscan2
- KLF15 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 36/346 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.04); catalogued as rs375056469; called by muse, mutect2
- KLHL25 | c.1287del p.L430Cfs*11 | Frame Shift Del (DEL) | VAF 41/325 reads (13%) | catalogued as rs1459896064; called by mutect2, pindel, varscan2
- KLHL36 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 43/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99257117; called by muse, mutect2, varscan2
- KMT2B | c.2884C>T p.R962C | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1385766471, COSV55859337; called by muse, mutect2, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 50/354 reads (14%) | catalogued as COSV55868319; called by mutect2, varscan2
- KMT2D | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1301516107, COSV56424806; called by muse, mutect2, varscan2
- KPNB1 | c.1981del p.Y661Mfs*13 | Frame Shift Del (DEL) | VAF 16/138 reads (12%) | catalogued as COSV51596824; called by mutect2, pindel
- KPTN | c.273del p.K92Sfs*22 | Frame Shift Del (DEL) | VAF 42/332 reads (13%) | catalogued as COSV99645797; called by mutect2, pindel, varscan2
- KRIT1 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 20/295 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs762646130; called by muse, mutect2
- KRT3 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 52/434 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs772879943, COSV58814764; called by muse, mutect2, varscan2
- KRT6A | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1481146150, COSV58106673; called by muse, mutect2, varscan2
- KRT8 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 29/286 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs940167416; called by muse, mutect2, varscan2
- KRT85 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.668); catalogued as rs138267130; called by muse, mutect2, varscan2
- LAMA1 | c.3597del p.D1200Tfs*38 | Frame Shift Del (DEL) | VAF 26/250 reads (10%) | catalogued as COSV101057516, COSV67542370; called by mutect2, varscan2
- LARGE1 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.735); catalogued as COSV100506358; called by muse, mutect2, varscan2
- LARGE1 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as rs188675457; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LBR | c.1786G>A p.G596S | Missense Mutation (SNP) | VAF 35/340 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55292342; called by muse, mutect2, varscan2
- LDHAL6A | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs777824686, COSV52649298; called by muse, mutect2, varscan2
- LDLRAD4 | c.876A>G p.I292M | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.081); catalogued as rs1183948577; called by muse, mutect2, varscan2
- LENG1 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 59/540 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.473); catalogued as rs1187302314; called by muse, mutect2, varscan2
- LGALS9 | c.1037dup p.D347Rfs*48 (on ENST00000395473 / NM_009587.3; = p.D315Rfs*48 on NM_002308.4) | Frame Shift Ins (INS) | VAF 30/275 reads (11%) | catalogued as rs775745717; called by mutect2, pindel
- LILRA2 | c.807G>A p.W269* | Nonsense Mutation (SNP) | VAF 54/489 reads (11%) | catalogued as rs1409086379, COSV99253148; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 30/183 reads (16%) | catalogued as rs780042765; called by mutect2, varscan2
- LMOD3 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 44/364 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.328); catalogued as rs774708945; called by muse, mutect2, varscan2
- LPAR3 | c.139del p.S47Lfs*9 | Frame Shift Del (DEL) | VAF 30/206 reads (15%) | catalogued as rs762083435; called by mutect2, varscan2
- LRFN5 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 40/323 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs373989159, COSV53249113; called by muse, mutect2, varscan2
- LRGUK | c.1983G>A p.A661= | Splice Region (SNP) | VAF 10/170 reads (6%) | catalogued as rs376097404, COSV104375691; called by muse, mutect2
- LRIG1 | c.1168_1171del p.F390Efs*21 | Frame Shift Del (DEL) | VAF 18/200 reads (9%) | catalogued as rs770438762; called by mutect2, pindel
- LRP1B | c.13072G>A p.V4358I | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs758650061; called by muse, mutect2, varscan2
- LRP1B | c.5382C>A p.D1794E | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV67288360; called by muse, mutect2, varscan2
- LRP4 | c.3091C>T p.P1031S | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV66136580; called by muse, mutect2
- LRRC10B | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.393); catalogued as rs903766316; called by muse, mutect2
- LRRC49 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779043538, COSV53013687; called by muse, mutect2, varscan2
- LRRC53 | c.1640del p.N547Ifs*12 | Frame Shift Del (DEL) | VAF 22/189 reads (12%) | catalogued as rs758068850; called by mutect2, pindel
- LRRC61 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 54/374 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs750768191; called by muse, mutect2, varscan2
- LRRC8B | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 31/320 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as rs750444236; called by muse, mutect2
- LY6G6F-LY6G6D | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.062); catalogued as rs759316788; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs1363590401; called by muse, mutect2, varscan2
- LY6H | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 56/538 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs775405237; called by muse, varscan2
- MAD1L1 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 45/356 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs747276194, COSV56226118; called by muse, mutect2, varscan2
- MAN1C1 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 24/267 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs750883027, COSV56042282; called by muse, mutect2
- MAP1B | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 46/338 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs147013566; called by muse, mutect2, varscan2
- MAP1B | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs756043501, COSV57107037; called by muse, mutect2, varscan2
- MAP1B | c.2896G>A p.A966T | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs770956923, COSV57102995; called by muse, mutect2
- MAP2 | c.4747C>T p.R1583C | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs760779247, COSV52283134, COSV52288569; called by muse, mutect2, varscan2
- MAP2K7 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 34/280 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156815343, COSV67607577, COSV67607584; called by muse, mutect2, varscan2
- MAP3K14 | c.1471C>T p.R491W | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1465112315; called by muse, mutect2, varscan2
- MAP3K21 | c.922T>C p.Y308H | Missense Mutation (SNP) | VAF 31/352 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777767106; called by muse, mutect2
- MAP3K9 | c.1547A>G p.N516S | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.119); catalogued as COSV101173811; called by muse, mutect2, varscan2
- MAP4K3 | c.569del p.G190Vfs*16 | Frame Shift Del (DEL) | VAF 16/151 reads (11%) | catalogued as rs1451169538; called by mutect2, pindel, varscan2
- MAPK7 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 41/331 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs564709382, COSV55189717; called by muse, mutect2, varscan2
- MAPK9 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756294947, COSV58118244; called by muse, mutect2, varscan2
- MATK | c.677C>T p.A226V (on ENST00000310132 / NM_139355.3; = p.A227V on NM_002378.4) | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs779864879; called by muse, mutect2, varscan2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 21/150 reads (14%) | catalogued as rs1203662025; called by mutect2, pindel, varscan2
- MAVS | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs555385198; called by muse, mutect2, varscan2
- MBP | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 12/181 reads (7%) | catalogued as COSV100592859; called by muse, mutect2
- MCMBP | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs202205398, COSV63510796; called by muse, mutect2, varscan2
- MDGA2 | c.2135T>C p.V712A (on ENST00000399232 / NM_001113498.2; = p.V414A on NM_182830.4) | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as COSV100636561; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 16/131 reads (12%) | catalogued as rs1180255648; called by mutect2, varscan2
- ME3 | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763282991, COSV62774533, COSV62774628; called by muse, mutect2, varscan2
- MEA1 | c.119A>G p.Q40R | Missense Mutation (SNP) | VAF 46/370 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs763536971; called by muse, mutect2, varscan2
- MED25 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs1376475717; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 85/346 reads (25%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MEDAG | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 21/178 reads (12%) | catalogued as COSV66849896; called by muse, mutect2, varscan2
- MEIS3 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs147207869; called by muse, mutect2, varscan2
- MEMO1 | c.622del p.E208Rfs*9 | Frame Shift Del (DEL) | VAF 28/190 reads (15%) | catalogued as COSV99703820; called by mutect2, pindel, varscan2
- METTL1 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs765853566, COSV55744963; called by muse, mutect2, varscan2
- METTL17 | c.1265+10del | Splice Region (DEL) | VAF 46/288 reads (16%) | catalogued as rs771419748, COSV100068730; called by mutect2, varscan2
- METTL3 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752850121; called by muse, mutect2, varscan2
- MFSD6L | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 45/381 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs1384292338, COSV99052227; called by muse, varscan2
- MGAM | c.5564G>A p.S1855N | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs1447177148; called by muse, mutect2
- MIDEAS | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 50/436 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs751165860, COSV54098999; called by muse, varscan2
- MIEF2 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 43/323 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs777504562; called by muse, mutect2, varscan2
- MIER1 | c.109C>T p.R37* (on ENST00000355356 / NM_001077701.3; = p.R54* on NM_020948.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 29/253 reads (11%) | catalogued as COSV62531189; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 65/254 reads (26%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MKI67 | c.5140A>G p.I1714V | Missense Mutation (SNP) | VAF 48/378 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs866579786; called by muse, mutect2, varscan2
- MLIP | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 39/292 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV51431790; called by muse, mutect2, varscan2
- MN1 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 54/384 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.654); catalogued as rs778534551; called by mutect2, varscan2
- MNX1 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 38/330 reads (12%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.015); catalogued as rs1259816325; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | catalogued as rs755830405; called by mutect2, varscan2
- MPO | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1481343975; called by muse, mutect2, varscan2
- MRGPRD | c.940G>A p.V314M | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs774928635, COSV58423415; called by muse, mutect2, varscan2
- MRTFA | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 48/409 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.866); catalogued as rs373666097, COSV62933025, COSV62935045; called by muse, mutect2, varscan2
- MSANTD2 | c.1168A>G p.M390V (on ENST00000374979 / NM_001308027.2; = p.M338V on NM_024631.4) | Missense Mutation (SNP) | VAF 46/299 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.145); catalogued as rs745787951; called by muse, mutect2, varscan2
- MST1R | c.3532C>T p.R1178W | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs878910700, COSV56576108; called by muse, mutect2, varscan2
- MTMR11 | c.1871T>C p.L624P (on ENST00000439741 / NM_001145862.2; = p.L552P on NM_181873.3) | Missense Mutation (SNP) | VAF 42/364 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54966173; called by muse, mutect2, varscan2
- MTNR1B | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs145010577, COSV57068470; called by muse, mutect2
- MTOR | c.7331C>T p.T2444M | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as rs769849522; called by muse, mutect2, varscan2
- MTRF1L | c.753del p.Q252Sfs*3 | Frame Shift Del (DEL) | VAF 16/174 reads (9%) | catalogued as rs762360173; called by mutect2, pindel
- MUC12 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 46/431 reads (11%) | SIFT deleterious, low confidence (0); catalogued as rs79948354; called by muse, mutect2
- MUC4 | c.14996C>T p.T4999M (on ENST00000463781 / NM_018406.7; = p.T763M on NM_004532.6) | Missense Mutation (SNP) | VAF 41/327 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.869); catalogued as rs367749099; called by muse, mutect2, varscan2
- MUC5AC | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT tolerated (0.9); catalogued as rs377067279; called by muse, mutect2, varscan2
- MUSK | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs369353843; called by muse, mutect2, varscan2
- MX1 | c.1936C>T p.R646W | Missense Mutation (SNP) | VAF 55/402 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753293594, COSV55819577; called by muse, mutect2, varscan2
- MYCBPAP | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs201047283; called by muse, mutect2, varscan2
- MYO15A | c.2575C>T p.R859C | Missense Mutation (SNP) | VAF 40/333 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.319); catalogued as rs1369300546; called by muse, mutect2, varscan2
- MYO15A | c.9812G>A p.R3271H | Missense Mutation (SNP) | VAF 32/268 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs373295633; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.5014del p.L1672Wfs*34 | Frame Shift Del (DEL) | VAF 65/364 reads (18%) | catalogued as COSV62751875; called by mutect2, varscan2
- MYO5A | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 49/318 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.777); catalogued as rs199561289; called by muse, mutect2, varscan2
- MYO9B | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 31/314 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs1192927828; called by muse, mutect2
- NAALADL1 | c.723dup p.S242Lfs*56 | Frame Shift Ins (INS) | VAF 40/372 reads (11%) | catalogued as rs761671591; called by mutect2, varscan2
- NAGA | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as rs1285743095; called by muse, mutect2
- NALCN | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs758366704, COSV51915323; called by muse, mutect2, varscan2
- NARS2 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV55249199; called by muse, mutect2
- NBAS | c.5737G>T p.A1913S | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs530483614; called by muse, mutect2, varscan2
- NBL1 | c.535del p.A179Lfs*31 | Frame Shift Del (DEL) | VAF 12/100 reads (12%) | catalogued as COSV57030850; called by mutect2, pindel
- NCAM2 | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs573485921; called by muse, mutect2, varscan2
- NCAPD3 | c.2725dup p.Q909Pfs*12 | Frame Shift Ins (INS) | VAF 42/253 reads (17%) | catalogued as rs770284236; called by mutect2, varscan2
- NCF2 | c.1256del p.N419Tfs*4 | Frame Shift Del (DEL) | VAF 17/150 reads (11%) | catalogued as CM064138; called by mutect2, pindel, varscan2
- NCKAP5L | c.3932dup p.G1312Rfs*10 | Frame Shift Ins (INS) | VAF 36/342 reads (11%) | catalogued as rs750891910; called by mutect2, pindel, varscan2
- NDST3 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs150758016; called by muse, mutect2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 33/242 reads (14%) | catalogued as rs747914168; called by mutect2, varscan2
- NECTIN4 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.155); catalogued as rs1192032514, COSV63513321, COSV63513957; called by muse, mutect2, varscan2
- NETO1 | c.1267T>C p.S423P | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV100198834; called by muse, mutect2, varscan2
- NEU3 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs769837017, COSV53636478; called by muse, mutect2, varscan2
- NFATC4 | c.493del p.A165Pfs*38 | Frame Shift Del (DEL) | VAF 48/318 reads (15%) | catalogued as rs751744912, COSV51604815; called by mutect2, varscan2
- NFKBID | c.794G>A p.R265Q (on ENST00000396901; = p.R417Q on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/351 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.145); catalogued as rs764013048, COSV61729997; called by muse, mutect2, varscan2
- NIM1K | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 46/425 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.792); catalogued as rs757015659, COSV58142908; called by muse, mutect2
- NINL | c.3346G>A p.A1116T | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs774313616; called by muse, mutect2, varscan2
- NINL | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 33/382 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs781641026; called by muse, mutect2
- NIPAL2 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 41/400 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs775233686, COSV57842364, COSV57843788; called by muse, mutect2, varscan2
- NKX3-1 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 69/537 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs747972625, COSV66512231; called by muse, mutect2, varscan2
- NKX6-2 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs1255183154; called by muse, varscan2
- NMBR | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201782506; called by muse, mutect2
- NNT | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 58/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759786744, COSV52923915, COSV52925313; called by muse, mutect2, varscan2
- NOC4L | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 47/402 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as rs201466638, COSV57960354; called by muse, mutect2, varscan2
- NODAL | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs754863183, COSV54661850; called by muse, mutect2, varscan2
- NOS3 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs1387008421; called by muse, varscan2
- NOXA1 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 64/423 reads (15%) | catalogued as rs1449262457; called by muse, mutect2, varscan2
- NPAS4 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs750781616, COSV60650409; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 30/205 reads (15%) | catalogued as rs776154715; called by mutect2, varscan2
- NRP1 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751563527; called by muse, mutect2, varscan2
- NSMF | c.1327C>T p.R443W (on ENST00000371475 / NM_001130969.3; = p.R441W on NM_015537.4) | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750724724; called by muse, mutect2
- NT5C1B | c.497C>A p.S166Y (on ENST00000359846 / NM_001199086.2; = p.S106Y on NM_033253.4) | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV58399823; called by muse, mutect2, varscan2
- NTAN1 | c.890del p.N297Mfs*63 | Frame Shift Del (DEL) | VAF 30/218 reads (14%) | catalogued as rs753931847; called by mutect2, varscan2
- NTNG1 | c.1501C>T p.R501W (on ENST00000370068 / NM_001113226.3; = p.R400W on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/381 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV64274760; called by muse, mutect2
- NTNG2 | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV62366656, COSV62368799; called by muse, mutect2, varscan2
- NUFIP2 | c.670del p.R224Gfs*16 | Frame Shift Del (DEL) | VAF 33/308 reads (11%) | catalogued as rs772197760; called by mutect2, pindel, varscan2
- NUP214 | c.681del p.V228Sfs*29 | Frame Shift Del (DEL) | VAF 29/202 reads (14%) | catalogued as rs771913112, COSV63912486; called by mutect2, varscan2
- NYAP1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 79/525 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV55722059; called by muse, mutect2, varscan2
- OAZ1 | c.662_663dup p.S223Lfs*72 | Frame Shift Ins (INS) | VAF 32/210 reads (15%) | catalogued as rs1381276805; called by mutect2, varscan2
- OBSCN | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 41/366 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.094); catalogued as rs900736229, COSV52815958; called by muse, mutect2, varscan2
- OBSCN | c.5623G>A p.A1875T | Missense Mutation (SNP) | VAF 59/314 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.769); catalogued as rs745945708; called by muse, mutect2, varscan2
- OBSCN | c.6071C>T p.A2024V | Missense Mutation (SNP) | VAF 58/456 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs756810557; ClinVar: likely benign; called by muse, mutect2, varscan2
- OBSCN | c.15604G>A p.E5202K | Missense Mutation (SNP) | VAF 29/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755758580, COSV99480483; called by muse, mutect2, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 24/234 reads (10%) | catalogued as CD000269; called by mutect2, pindel
- OR10G3 | c.368G>T p.R123M | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745687033; called by muse, mutect2
- OR10R2 | c.206T>C p.I69T | Missense Mutation (SNP) | VAF 33/319 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.918); catalogued as rs370766542; called by muse, mutect2, varscan2
- OR3A1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 37/300 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146171012; called by muse, mutect2, varscan2
- OR4E1 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs386775423; called by muse, mutect2
- OR51F1 | c.853A>G p.M285V | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); catalogued as rs750824285; called by muse, mutect2
- OR52W1 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1404500152; called by muse, mutect2, varscan2
- OR6C68 | c.767T>A p.I256N | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.939); catalogued as COSV99059222; called by muse, mutect2, varscan2
- OR8H1 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 18/257 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57293753; called by muse, mutect2
- OSMR | c.1849del p.T617Qfs*20 | Frame Shift Del (DEL) | VAF 20/158 reads (13%) | catalogued as rs762315064; called by mutect2, pindel, varscan2
- OTOG | c.7729G>A p.A2577T | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs752447596; called by muse, mutect2, varscan2
- OVGP1 | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.069); catalogued as rs1227462011; called by muse, mutect2, varscan2
- P2RX3 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs570530884, COSV54441971; called by muse, mutect2, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 26/226 reads (12%) | catalogued as rs772816756; called by mutect2, pindel
- PARD6G | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 24/445 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs34386165; called by muse, mutect2
- PARP10 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 45/366 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1554748299; called by muse, mutect2, varscan2
- PATJ | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 30/247 reads (12%) | catalogued as rs774855207, COSV57159073; called by muse, mutect2, varscan2
- PATL1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.104); catalogued as rs1416127845, COSV55687670; called by muse, mutect2, varscan2
- PBRM1 | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs755255835, COSV56276373; called by muse, mutect2, varscan2
- PBRM1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.908); catalogued as rs1359676390, COSV56269219; called by muse, mutect2, varscan2
- PCCA | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs570674073, COSV100886348; called by muse, mutect2
- PCDH10 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 43/378 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs375893532, COSV52090936, COSV99074919; called by muse, mutect2, varscan2
- PCDH8 | c.2356del p.A786Pfs*151 | Frame Shift Del (DEL) | VAF 48/334 reads (14%) | catalogued as rs770663005, COSV100131664; called by mutect2, pindel, varscan2
- PCDH9 | c.1649C>A p.P550H | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100124519; called by muse, mutect2
- PCDHA12 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 57/487 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.298); catalogued as COSV56544132; called by muse, mutect2, varscan2
- PCDHA13 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56489611; called by muse, mutect2, varscan2
- PCDHAC1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 27/298 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV53861126; called by muse, mutect2
- PCDHB13 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 66/510 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53400502; called by muse, mutect2, varscan2
- PCDHB6 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.261); catalogued as rs17844433, COSV50701853; called by muse, mutect2, varscan2
- PCDHGA1 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 42/510 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.047); catalogued as rs967503819; called by muse, mutect2
- PCDHGA2 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 51/496 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV53906010; called by muse, mutect2, varscan2
- PCIF1 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV100976113; called by muse, mutect2, varscan2
- PCLO | c.218del p.P73Rfs*63 | Frame Shift Del (DEL) | VAF 24/254 reads (9%) | catalogued as COSV61623402; called by mutect2, pindel
- PDE2A | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as rs1380350373, COSV100558096; called by muse, mutect2
- PDPK1 | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 25/209 reads (12%) | catalogued as COSV51912234; called by muse, mutect2, varscan2
- PDZD2 | c.5528del p.K1843Rfs*31 | Frame Shift Del (DEL) | VAF 32/294 reads (11%) | catalogued as rs1184879635; called by mutect2, varscan2
- PDZRN3 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as rs1451880959; called by muse, mutect2, varscan2
- PER2 | c.3439G>A p.V1147I | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as rs774829432, COSV54522628; called by muse, mutect2, varscan2
- PES1 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs575214281; called by muse, varscan2
- PFKFB4 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 39/337 reads (12%) | PolyPhen possibly damaging (0.59); catalogued as rs781167335, COSV51682945; called by muse, mutect2, varscan2
- PGBD5 | c.734C>T p.A245V (on ENST00000525115; = p.A314V on NM_001258311.2) | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as rs1488372662, COSV58413566; called by muse, mutect2, varscan2
- PGLYRP2 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 48/369 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs773237573; called by muse, mutect2, varscan2
- PHACTR1 | c.759dup p.P254Afs*78 | Frame Shift Ins (INS) | VAF 42/274 reads (15%) | catalogued as rs749326031; called by mutect2, varscan2
- PHKG2 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 32/337 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs147950160; called by muse, mutect2, varscan2
- PIEZO2 | c.2800A>G p.M934V | Missense Mutation (SNP) | VAF 64/401 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1198428801; called by muse, mutect2, varscan2
- PIK3R1 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 36/312 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.976); catalogued as rs547196342, COSV99074073; called by muse, mutect2, varscan2
- PIKFYVE | c.2753C>A p.P918H | Missense Mutation (SNP) | VAF 49/344 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV52238833; called by muse, mutect2, varscan2
- PIKFYVE | c.4619C>T p.A1540V | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.078); catalogued as rs373049869; called by muse, mutect2, varscan2
- PIKFYVE | c.6067C>T p.R2023* | Nonsense Mutation (SNP) | VAF 12/198 reads (6%) | catalogued as rs750096185, COSV100010777; called by muse, mutect2
- PITHD1 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1400129340; called by muse, mutect2
- PITPNM1 | c.2965C>T p.R989C | Missense Mutation (SNP) | VAF 44/347 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs1272992370, COSV99653498; called by muse, varscan2
- PITPNM1 | c.2891C>T p.S964L | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV54160838; called by muse, varscan2
- PJA2 | c.1696A>G p.I566V | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.729); catalogued as rs1381376106; called by muse, mutect2
- PKD2 | c.2593G>A p.V865M | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as rs1245147089; called by muse, mutect2
- PKHD1 | c.3734C>T p.A1245V | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs140815495; called by muse, mutect2, varscan2
- PKP1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 38/321 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs1057162135, COSV55819926; called by muse, mutect2, varscan2
- PKP1 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 39/292 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs369928249; called by muse, mutect2, varscan2
- PKP3 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.328); catalogued as rs777411352; called by muse, mutect2
- PKP4 | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1054707191, COSV61578999; called by muse, mutect2, varscan2
- PLA2G12A | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 26/250 reads (10%) | catalogued as rs1296033628; called by muse, mutect2
- PLA2G1B | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369316608; called by muse, mutect2, varscan2
- PLA2G4D | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 67/474 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV51820000; called by muse, mutect2, varscan2
- PLA2G4D | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs148579768; called by muse, mutect2, varscan2
- PLA2R1 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 39/338 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.606); catalogued as rs1188014540; called by muse, mutect2, varscan2
- PLCB3 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs199676501; called by muse, mutect2
- PLEKHG2 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 41/339 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs376501202; called by muse, mutect2, varscan2
- PLEKHG4 | c.2963G>A p.S988N | Missense Mutation (SNP) | VAF 48/304 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58574411; called by muse, mutect2, varscan2
- PLG | c.91del p.A31Lfs*16 | Frame Shift Del (DEL) | VAF 30/258 reads (12%) | catalogued as COSV99805210; called by mutect2, pindel
- PLIN4 | c.1021G>A p.G341S (on ENST00000301286; = p.G356S on NM_001367868.2) | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs377602894; called by muse, varscan2
- PLK3 | c.1357G>C p.A453P | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs201492855, COSV59499068; called by muse, mutect2, varscan2
- PMM1 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs749406595; called by muse, mutect2, varscan2
- PNPLA6 | c.3547C>T p.R1183W (on ENST00000414982 / NM_001166111.2; = p.R1135W on NM_006702.5) | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766389806, COSV55381353; called by muse, mutect2
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 40/355 reads (11%) | catalogued as rs761459630; called by mutect2, pindel, varscan2
- POM121L12 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 52/470 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs749109595, COSV101374850; called by muse, varscan2
- POM121L12 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 60/532 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV68692951, COSV68693360; called by muse, varscan2
- POPDC3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as rs111547826, COSV54643244; called by muse, mutect2
- POTEA | c.1687del p.M563* (on ENST00000519951 / NM_001005365.2; = p.M517* on NM_001002920.1) | Frame Shift Del (DEL) | VAF 18/128 reads (14%) | catalogued as rs905717954; called by mutect2, varscan2
- PPFIA1 | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.432); catalogued as rs767181650; called by muse, mutect2, varscan2
- PPFIBP2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs201767093, COSV55076609; called by muse, varscan2
- PPFIBP2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs112515313; called by muse, mutect2, varscan2
- PPFIBP2 | c.2464G>A p.G822R | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs565797746, COSV55077796; called by muse, mutect2, varscan2
- PPM1E | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57572232; called by muse, mutect2, varscan2
- PPP1R18 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 52/460 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs199657379; called by muse, mutect2, varscan2
- PPP1R3A | c.1361C>A p.P454H | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV52875965, COSV52877899; called by muse, mutect2
- PRDM2 | c.4768A>G p.K1590E | Missense Mutation (SNP) | VAF 40/311 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs1166590013, COSV52454422; called by muse, mutect2, varscan2
- PRDM8 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 48/280 reads (17%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.977); catalogued as rs776357035; called by muse, mutect2, varscan2
- PREPL | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs202130215; called by muse, mutect2, varscan2
- PRIMA1 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs200782279, COSV60263331; called by muse, mutect2, varscan2
- PRKACB | c.640A>G p.K214E | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs756857310; called by muse, mutect2
- PRKAR1A | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104423139; called by muse, mutect2, varscan2
- PRKN | c.1060G>T p.G354W | Missense Mutation (SNP) | VAF 38/314 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV58210320, COSV58244936; called by muse, mutect2, varscan2
- PRORP | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 42/329 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs747777191, COSV51618238; called by muse, mutect2, varscan2
- PRR14L | c.5514dup p.R1839Tfs*98 | Frame Shift Ins (INS) | VAF 43/248 reads (17%) | catalogued as rs1014643130; called by mutect2, varscan2
- PRR5-ARHGAP8 | c.1037T>C p.V346A (on ENST00000352766; = p.V267A on NM_181334.5) | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs1461653718; called by muse, mutect2, varscan2
- PRRX2 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 45/367 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs566612578, COSV65243496; called by muse, mutect2, varscan2
- PRUNE2 | c.6637G>A p.D2213N | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV65040561; called by muse, mutect2
- PSEN1 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 41/336 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as COSV99997613; called by muse, mutect2, varscan2
- PSMC4 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as rs1424317805; called by muse, mutect2, varscan2
- PSTPIP1 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777380464; ClinVar: uncertain significance; called by muse, varscan2
- PTPN3 | c.2021A>G p.N674S | Missense Mutation (SNP) | VAF 32/315 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52711823; called by muse, mutect2, varscan2
- PTPRN2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 41/361 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs751826612, COSV67023843, COSV67027410; called by muse, mutect2, varscan2
- PTPRS | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 56/460 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs778054699, COSV53620450; called by muse, mutect2, varscan2
- PTPRT | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs867189940; called by muse, mutect2
- PUS7L | c.1203dup p.Q402Tfs*4 | Frame Shift Ins (INS) | VAF 15/123 reads (12%) | catalogued as rs1361634403; called by mutect2, varscan2
- PWWP3A | c.1906G>A p.V636I (on ENST00000627377; = p.V635I on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.048); catalogued as rs748597980; called by muse, mutect2, varscan2
- PXDN | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.392); catalogued as rs777271860; called by muse, mutect2, varscan2
- PXDNL | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 25/364 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs371935059, COSV62501027; called by muse, mutect2
- QRFPR | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 29/254 reads (11%) | catalogued as rs989174472, COSV57676413; called by muse, mutect2, varscan2
- QSOX2 | c.822C>T p.V274= | Splice Region (SNP) | VAF 24/238 reads (10%) | catalogued as rs372271403; called by muse, mutect2
- RAB11FIP2 | c.1101del p.D368Ifs*19 | Frame Shift Del (DEL) | VAF 24/218 reads (11%) | catalogued as rs35192242, COSV62924876; called by mutect2, pindel
- RAB11FIP5 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.355); catalogued as rs765024791, COSV50247738; called by muse, mutect2, varscan2
- RADIL | c.1169del p.G390Efs*33 | Frame Shift Del (DEL) | VAF 31/320 reads (10%) | catalogued as rs1479966997; called by mutect2, varscan2
- RAG1 | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs770953505, COSV55026394; called by muse, mutect2, varscan2
- RALGPS1 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 28/353 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1299070016; called by muse, mutect2
- RAP1GAP2 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 45/322 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); catalogued as rs776769717, COSV54590216; called by muse, mutect2, varscan2
- RAPGEF1 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1351541945, COSV64698951; called by muse, mutect2, varscan2
- RAPGEF4 | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1487581200; called by muse, mutect2, varscan2
- RASGRF1 | c.2989C>T p.R997W | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1408846093, COSV67249854; called by muse, mutect2
- RASGRF1 | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 45/360 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1302220075, COSV67249735; called by muse, mutect2, varscan2
- RBM17 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101158995; called by muse, mutect2
- RBM23 | c.1184C>T p.A395V (on ENST00000359890 / NM_001077351.2; = p.A379V on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs1377208218; called by mutect2, varscan2
- RBMXL1 | c.1154del p.G385Efs*31 | Frame Shift Del (DEL) | VAF 24/178 reads (13%) | catalogued as COSV99555546; called by mutect2, pindel, varscan2
- RCHY1 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 19/154 reads (12%) | catalogued as rs1180170921, COSV61009811; called by muse, mutect2, varscan2
- RD3 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 37/380 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV100879225; called by muse, mutect2, varscan2
- RFPL4B | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs145350912; called by muse, mutect2, varscan2
- RFXANK | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 41/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748578827, COSV57393127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGS12 | c.3556G>A p.E1186K | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs267600139, COSV58749043; called by muse, varscan2
- RIBC2 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs200022735; called by muse, mutect2, varscan2
- RIN3 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 44/347 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs138313947; called by muse, mutect2, varscan2
- RIPOR3 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371121479; called by muse, mutect2, varscan2
- RNF112 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.834); catalogued as COSV71327088; called by muse, mutect2
- RNF19B | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs572681471; called by muse, mutect2
- RNF32 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs561586118, COSV58732566; called by mutect2, varscan2
- RNF40 | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs907447641; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 76/329 reads (23%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- RPGRIP1L | c.3301G>A p.A1101T | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs539084201; ClinVar: uncertain significance; called by muse, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 48/228 reads (21%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RREB1 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 60/393 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs923585439; called by muse, mutect2, varscan2
- RTL1 | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 46/353 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1566753444; called by muse, mutect2, varscan2
- RTL5 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV65454190; called by muse, mutect2, varscan2
- RTL6 | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 56/374 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.955); catalogued as rs1428562718; called by muse, mutect2, varscan2
- RUBCN | c.2090G>A p.R697Q | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56377279; called by muse, mutect2, varscan2
- RUFY2 | c.457del p.M153Wfs*8 | Frame Shift Del (DEL) | VAF 30/190 reads (16%) | catalogued as rs759904440; called by mutect2, varscan2
- RYR1 | c.6640G>A p.V2214I | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs193922795, CM014979, COSV62089746; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.12953G>A p.R4318Q | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs1348435999; called by muse, mutect2, varscan2
- RYR2 | c.12719C>T p.T4240M | Missense Mutation (SNP) | VAF 38/317 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV63714535; called by muse, mutect2, varscan2
- SALL4 | c.2989A>G p.T997A | Missense Mutation (SNP) | VAF 27/372 reads (7%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.97); catalogued as COSV53852790; called by muse, mutect2
- SAMD9L | c.4374del p.F1459Sfs*26 | Frame Shift Del (DEL) | VAF 29/234 reads (12%) | catalogued as COSV100560185; called by mutect2, pindel, varscan2
- SART1 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 49/396 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs377371371, COSV100409011; called by muse, mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 20/238 reads (8%) | catalogued as COSV54589079; called by mutect2, pindel
- SCAMP2 | c.93G>T p.Q31H | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1479392544; called by muse, mutect2, varscan2
- SCLT1 | c.1844G>A p.R615Q | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); catalogued as rs372975601; called by muse, mutect2, varscan2
- SCN11A | c.4029del p.K1343Nfs*10 | Frame Shift Del (DEL) | VAF 17/168 reads (10%) | catalogued as rs1325097401; called by mutect2, pindel, varscan2
- SCN3A | c.116del p.K39Rfs*53 | Frame Shift Del (DEL) | VAF 31/249 reads (12%) | catalogued as rs34966371; called by mutect2, pindel, varscan2
- SCUBE1 | c.2557G>A p.D853N | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs758646314, COSV62613274; called by muse, mutect2, varscan2
- SDC2 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 38/394 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as COSV100144205; called by muse, mutect2
- SDK1 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 33/343 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.394); catalogued as rs557260722, COSV67381922; called by muse, mutect2, varscan2
- SDR42E2 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs561060648; called by muse, mutect2, varscan2
- SEC13 | c.694G>A p.A232T (on ENST00000350697 / NM_183352.3; = p.A235T on NM_030673.4) | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150466597; called by muse, mutect2, varscan2
- SEC16A | c.6197del p.P2066Qfs*76 | Frame Shift Del (DEL) | VAF 49/338 reads (14%) | catalogued as COSV99256980; called by mutect2, pindel, varscan2
- SEC16A | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 30/460 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs560120664; called by muse, mutect2
- SEC63 | c.1586_1596delinsGAAACCTTT p.K529Rfs*4 | Frame Shift Del (DEL) | VAF 26/212 reads (12%) | catalogued as COSV64602454; called by pindel, varscan2*
- SEMA6A | c.3028G>A p.V1010I | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.404); catalogued as rs1476530522; called by muse, mutect2, varscan2
- SERINC1 | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1562215724; called by muse, mutect2, varscan2
- SERPINA2 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 44/297 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs868355872; called by muse, mutect2, varscan2
- SERPINA3 | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV67586838; called by muse, mutect2
- SERPINB13 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 31/244 reads (13%) | catalogued as rs200737594, COSV99501207; called by muse, mutect2, varscan2
- SERTAD4 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs202049013, COSV100882624; called by muse, mutect2
- SETD1A | c.4211C>T p.P1404L | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs575800239, COSV99353713; called by muse, mutect2, varscan2
- SETMAR | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 23/256 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs575057889; called by muse, mutect2, varscan2
- SF3A2 | c.995del p.P332Qfs*114 | Frame Shift Del (DEL) | VAF 30/231 reads (13%) | catalogued as rs771822076; called by mutect2, pindel, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 19/174 reads (11%) | catalogued as rs1260834379; called by mutect2, pindel, varscan2
- SH3PXD2B | c.2278C>T p.R760C | Missense Mutation (SNP) | VAF 39/369 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs199590644, COSV61125233; called by muse, mutect2, varscan2
- SHKBP1 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs1268661989, COSV52539168; called by muse, mutect2, varscan2
- SHROOM2 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as rs1277035899; called by muse, mutect2, varscan2
- SI | c.4601dup p.N1535Qfs*30 | Frame Shift Ins (INS) | VAF 19/184 reads (10%) | catalogued as rs779227756; called by mutect2, pindel
- SIPA1L1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs542018760, COSV62169330; called by muse, mutect2, varscan2
- SIX3 | c.221del p.P74Rfs*177 | Frame Shift Del (DEL) | VAF 20/164 reads (12%) | catalogued as rs760462666, COSV53226999; called by pindel, varscan2
- SIX3 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 53/360 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV53228498; called by muse, mutect2, varscan2
- SKOR1 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 44/335 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759626775, COSV58249675; called by muse, mutect2, varscan2
- SLC1A4 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs780694983, COSV52233873; called by muse, mutect2
- SLC22A12 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs529746726; called by muse, mutect2
1,674 further variants in this file (1,018 protein-altering or splice-affecting, 555 silent, 101 other) are not listed here.
